Surgical pathology report (de-identified scan), TCGA case TCGA-F7-A61V, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-A61V-01A (Primary Tumor).

[page 1 of 2]
Gross Description: A. "Left deep tongue margin." 3 fragments of red-tan tissue, each 0.5 cm. All processed for frozen section. Frozen section control, All processed, A1.

B. "Left tongue (suture towards tongue base)."

Microscopic Description: Procedure: Resection, partial glossectomy

Specimen integrity: Intact

Specimen size: 4.0 x 3.0 x 2.0 cm

Laterality: Left

Tumor site: Base of tongue

Tumor focality: Single focus

Tumor size: 2.3 cm greatest dimension

Tumor thickness: 1.0 cm

Histologic type: Squamous cell carcinoma, conventional

Histologic grade: Grade 1

Margins: Uninvolved by invasive or in-situ carcinoma.

Lymph-vascular invasion: Absent

Perineural invasion: Absent

Stage: pT2 N0

SUBMANDIBULAR GLAND (LEFT): UNREMARKABLE.

LYMPH NODES (LEFT NECK, LEVEL 1): NO NEOPLASM (2 NODES EXAMINED).

LYMPH NODES (LEFT NECK, LEVEL 2): NO NEOPLASM (7 NODES EXAMINED).

LYMPH NODES (LEFT NECK, LEVEL 3): NO NEOPLASM (35 NODES EXAMINED).

LYMPH NODES (LEFT NECK, LEVEL 4): NO NEOPLASM (18 NODES EXAMINED).

Diagnosis Details: Tongue (Base, left side): Invasive keratinizing squamous cell carcinoma

ICD-O-3

Carcinoma, squamous cell NOS
857013

Site: Base of tongue
C01.9

QW 4/12/13

[page 2 of 2]
Comments: The largest lymph node is 2.2 cm. It has been entirely processed. It exhibits marked follicular hyperplasia, but there is no metastatic neoplasm.

Formatted Path Reports: HEAD & NECK CHECKLIST

Procedure: Resection, partial glossectomy

Specimen integrity: Intact

Specimen size: 4.0 x 3.0 x 2.0 cm

Tumor site: Base of tongue

Tumor focality: Single focus

Tumor size: 2.3 cm greatest dimension

Tumor thickness: 1.0 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Well differentiated

Margins: Uninvolved by invasive or in-situ carcinoma.

Lymph-vascular invasion: Absent

Perineural invasion: Absent

Laterality: Left

Source: NCI Genomic Data Commons file 8cdeb7c0-4944-4e79-9a7a-0b6cf7b38280 (TCGA-F7-A61V.02E2D36A-F974-426C-BF6F-5880FA8E5C32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).